Somatic mutation profile of tumor specimen TARGET-50-PAJMKN-01A (aliquot TARGET-50-PAJMKN-01A-01D) from TARGET case TARGET-50-PAJMKN, project TARGET-WT (High-Risk Wilms Tumor). Sex at birth: female; Vital status: Alive; Primary diagnosis: Wilms tumor; Tissue or organ of origin: Kidney, NOS; Age at diagnosis: 1.4 years (521 days).
Specimen TARGET-50-PAJMKN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02b0ff55-5fb8-4163-a791-1096c45987e2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-50-PAJMKN-10A (Blood Derived Normal), aliquot TARGET-50-PAJMKN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/182e6d59-d090-4b43-baf0-306cb5ed76a6

The open-access MAF lists 1 somatic variant for this specimen: 1 protein-altering or splice-affecting.
By variant classification: Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SERINC2 | c.923T>A p.V308E (on ENST00000373709 / NM_178865.5; = p.V312E on NM_018565.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.003); called by muse, mutect2
